Somatic mutation profile of tumor specimen TARGET-40-NAAIBW-01A (aliquot TARGET-40-NAAIBW-01A-01D) from TARGET case TARGET-40-NAAIBW, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.3 years (3,031 days).
Specimen TARGET-40-NAAIBW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a39ecc7-73cc-4290-b0e4-038a0e67dbc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAIBW-10B (Blood Derived Normal), aliquot TARGET-40-NAAIBW-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/693ceba5-0e28-49d7-9e2a-7cf92f6ad55e

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 6 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 6, Intron 5, RNA 4, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL441992.2 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1156602850; called by muse, mutect2
- DCDC2C | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as rs1211453184; called by muse, mutect2, varscan2
- DCTN4 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 102/139 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200145293; called by muse, mutect2, varscan2
- FBN3 | c.7804G>C p.D2602H | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99560959; called by muse, mutect2, varscan2
- GLDN | c.223_242del p.A75Tfs*29 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs1020390963; called by mutect2, pindel, varscan2
- LCE6A | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV70391215; called by muse, mutect2, varscan2
- MEIS3 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1478277856; called by muse, mutect2, varscan2
- OR1L1 | c.596_598del p.F199del (on ENST00000373686; = p.F149del on NM_001005236.3) | In Frame Del (DEL) | VAF 128/299 reads (43%) | catalogued as rs1439976743; called by mutect2, pindel, varscan2
- OR6C3 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); catalogued as rs751906223, COSV65571563; called by muse, mutect2, varscan2
- PTPRO | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); catalogued as COSV55510831; called by muse, mutect2, varscan2
- RPGRIP1 | c.1456A>C p.T486P | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs752788894; called by muse, mutect2, varscan2
- SLC25A36 | c.875T>C p.I292T (on ENST00000324194 / NM_001104647.3; = p.I291T on NM_018155.3) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60781926; called by muse, mutect2, varscan2
- ZNF775 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779991517; called by muse, mutect2
- AANAT | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATXN2 | c.2945A>T p.Y982F (on ENST00000550104; = p.Y822F on NM_002973.4) | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CS | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.8062_8064del p.K2688del (on ENST00000409039; = p.K2627del on NM_207437.3) | In Frame Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- DNHD1 | c.5471C>T p.P1824L | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFALS | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JMJD1C | c.4462G>T p.A1488S | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KIF17 | c.2972C>A p.P991H | Missense Mutation (SNP) | VAF 102/109 reads (94%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); called by muse, varscan2
- KRT9 | c.994C>G p.Q332E | Missense Mutation (SNP) | VAF 159/406 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRT9 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 162/412 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIG4 | c.2441G>C p.R814P | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NAA25 | c.1991G>A p.W664* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- NWD1 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6K6 | c.700A>T p.I234F (on ENST00000368144; = p.I210F on NM_001005184.1) | Missense Mutation (SNP) | VAF 81/375 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PKD1 | c.7968C>G p.H2656Q | Missense Mutation (SNP) | VAF 162/300 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PLEKHA7 | c.3208A>G p.K1070E | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PPARG | c.1307A>C p.D436A (on ENST00000287820 / NM_015869.5; = p.D406A on NM_005037.7) | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PPM1H | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PTEN | c.191A>C p.H64P | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RAD54L2 | c.4099C>G p.P1367A | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- RP1 | c.3591T>A p.S1197R | Missense Mutation (SNP) | VAF 311/527 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- SCART1 | c.1517C>G p.T506S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TET1 | c.2257G>C p.V753L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- TUBA1C | c.1316G>C p.S439T | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.024); called by muse, mutect2
- WASH6P | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by mutect2, varscan2
- ZNF749 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- MAN1A1 | c.744T>C p.L248= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
- MUC3A | c.123C>T p.S41= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs573026294, COSV100115070; called by muse, mutect2, varscan2
- RBL1 | c.1188G>C p.R396= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs1436725963; called by muse, mutect2, varscan2
- TP73 | c.69A>G p.E23= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- UBA1 | c.1770C>T p.Y590= | Silent (SNP) | VAF 148/413 reads (36%) | catalogued as rs782725019; called by muse, mutect2, varscan2
- WASH6P | c.309C>T p.S103= | Silent (SNP) | VAF 24/192 reads (13%) | called by muse, mutect2, varscan2
- AC011487.1 | n.325C>T | RNA (SNP) | VAF 47/266 reads (18%) | catalogued as rs1480778904; called by muse, varscan2
- AC022137.2 | chr19:53423122 C>T | 3'Flank (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- FGB | c.115-25T>A | Intron (SNP) | VAF 52/112 reads (46%) | called by mutect2, varscan2
- FTSJ1 | c.122-42G>T | Intron (SNP) | VAF 98/259 reads (38%) | called by muse, mutect2, varscan2
- GAB3 | c.1644+797G>C | Intron (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- HERC2P2 | n.985A>C | RNA (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- LINC01547 | n.3441C>G | RNA (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- NCKAP1L | c.1339-52C>G | Intron (SNP) | VAF 12/164 reads (7%) | catalogued as rs1193961801; called by muse, mutect2
- SPG7 | c.183+126G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs542343926; called by muse, mutect2, varscan2
- WASH8P | n.400C>T | RNA (SNP) | VAF 57/434 reads (13%) | called by muse, mutect2, varscan2
